Somatic mutation profile of tumor specimen MP2PRT-PATANZ-TMP1-A (aliquot MP2PRT-PATANZ-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PATANZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,273 days).
Specimen MP2PRT-PATANZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1bb5f44-5930-419e-a606-cd99a0a77246.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATANZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATANZ-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2807bd78-c01e-4588-9811-3748ad1606a8

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 4, Silent 4, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.845G>T p.R282L | Missense Mutation (SNP) | VAF 182/667 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882008, CM004344, COSV52689673, COSV52773873, COSV52969460, COSV53068318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERG | c.1109A>C p.D370A (on ENST00000398919 / NM_001243428.1; = p.D346A on NM_004449.4) | Missense Mutation (SNP) | VAF 341/1018 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55729043; called by muse, mutect2, varscan2
- ALMS1 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.486); called by muse, mutect2
- IGLV4-60 | c.362delinsCTCAAC | In Frame Ins (INS) | VAF 83/214 reads (39%) | called by pindel, varscan2*
- MYC | c.188_208delinsTTG p.P63_C70delinsLG (on ENST00000377970; = p.P78_C85delinsLG on NM_002467.6) | In Frame Del (DEL) | VAF 178/554 reads (32%) | called by pindel, varscan2*
- SOX9 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 246/774 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ADGRD2 | c.2442C>T p.Y814= | Silent (SNP) | VAF 198/632 reads (31%) | catalogued as rs758745872; called by muse, mutect2, varscan2
- DPYSL4 | c.1368C>T p.D456= | Silent (SNP) | VAF 203/647 reads (31%) | catalogued as rs773720558; called by muse, mutect2, varscan2
- RUVBL2 | c.102C>T p.D34= | Silent (SNP) | VAF 183/390 reads (47%) | catalogued as rs200990353; called by muse, mutect2, varscan2
- ZNF735 | c.807C>T p.Y269= | Silent (SNP) | VAF 30/532 reads (6%) | catalogued as rs374391910; called by muse, mutect2
